Somatic mutation profile of tumor specimen TCGA-R6-A6L6-01B (aliquot TCGA-R6-A6L6-01B-11D-A33E-09) from TCGA case TCGA-R6-A6L6, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G3; Age at diagnosis: 68.7 years (25,092 days).
Specimen TCGA-R6-A6L6-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 606338da-29ee-4ff9-aea8-8d845c118638.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R6-A6L6-10A (Blood Derived Normal), aliquot TCGA-R6-A6L6-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b57529c-b1df-4e11-93ed-47f5b476e39d

The open-access MAF lists 114 somatic variants for this specimen: 87 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 25, Frame Shift Ins 4, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 3, 5'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs387906660, CM092077, CM092078, COSV56289992; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as rs939108810, COSV65401263; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1938G>A p.M646I | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs757487098; called by muse, mutect2, varscan2
- ARHGAP15 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as rs1223428561; called by muse, mutect2, varscan2
- ARHGEF17 | c.3766C>T p.R1256W | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs1044101306, COSV55237544; called by muse, mutect2, varscan2
- CTNND1 | c.2108G>T p.R703L (on ENST00000399050 / NM_001085458.2; = p.R697L on NM_001331.3) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62386183; called by muse, mutect2, varscan2
- CUBN | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.416); catalogued as COSV64715599; called by muse, mutect2, varscan2
- DDX25 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs759810402; called by muse, mutect2, varscan2
- DMD | c.8330G>A p.R2777K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.155); catalogued as COSV58903017; called by muse, mutect2, varscan2
- DNAH8 | c.2869G>T p.E957* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as COSV100543198, COSV59472061; called by muse, mutect2, varscan2
- EDNRB | c.42C>A p.S14R | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV57527097; called by muse, mutect2
- FCN1 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.034); catalogued as rs761311523, COSV65662543; called by mutect2, varscan2
- FMN2 | c.4858G>T p.A1620S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV60430401; called by muse, mutect2
- FOXR1 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144422939; called by muse, mutect2, varscan2
- FREM2 | c.3773T>C p.I1258T | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1396920486; called by muse, mutect2
- FRMD6 | c.682G>A p.D228N (on ENST00000344768 / NM_001267046.2; = p.D220N on NM_152330.4) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746951707; called by muse, mutect2, varscan2
- GCSAML | c.355A>T p.R119W | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV63576974; called by muse, mutect2, varscan2
- ITGB2 | c.744G>A p.E248= | Splice Region (SNP) | VAF 8/110 reads (7%) | catalogued as rs1404784957; called by muse, mutect2
- KATNAL2 | c.811G>A p.V271M (on ENST00000356157 / NM_001353899.1; = p.V199M on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1467183397; called by muse, mutect2, varscan2
- KRT73 | c.702T>A p.N234K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1353846433; called by muse, mutect2, varscan2
- LPA | c.5064C>A p.C1688* | Nonsense Mutation (SNP) | VAF 26/126 reads (21%) | catalogued as COSV100308365; called by muse, mutect2, varscan2
- OR7E24 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs201669790; called by muse, mutect2, varscan2
- PATL1 | c.788G>C p.R263T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV100274792; called by muse, mutect2, varscan2
- PCDHGA12 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52745510; called by muse, mutect2
- PIK3R3 | c.1187+1G>T p.X396_splice | Splice Site (SNP) | VAF 4/44 reads (9%) | catalogued as rs1370712534; called by muse, mutect2
- PPP1R3D | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV62565009; called by muse, mutect2, varscan2
- SKAP2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1025140851, COSV61725796; called by muse, mutect2
- SLC9B1 | c.830-1G>A p.X277_splice | Splice Site (SNP) | VAF 10/82 reads (12%) | catalogued as COSV56467562; called by muse, varscan2
- TMEM62 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as COSV53042151; called by muse, mutect2, varscan2
- TRPA1 | c.387C>G p.F129L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV100084956; called by muse, mutect2, varscan2
- TTC14 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV56012972; called by muse, mutect2, varscan2
- UGT1A4 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs538242607; called by muse, mutect2, varscan2
- UNC13A | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.493); catalogued as rs763300244, COSV53191419; called by muse, mutect2, varscan2
- USP28 | c.1877G>C p.W626S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1223742807; called by muse, mutect2, varscan2
- YTHDC2 | c.2056C>G p.L686V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs544302245; called by muse, varscan2
- ZNF254 | c.274C>G p.Q92E | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV100741720; called by muse, varscan2
- ZNF423 | c.3176C>T p.A1059V (on ENST00000563137 / NM_001379286.1; = p.A1051V on NM_015069.4) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.108); catalogued as rs750497057, COSV99283087; called by muse, mutect2, varscan2
- ABCA6 | c.4523A>G p.Y1508C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC068580.4 | c.284T>G p.V95G | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- ACADL | c.275_276insG p.A93Sfs*43 | Frame Shift Ins (INS) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- ADGRF1 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- ARHGAP36 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, varscan2
- ATP6AP2 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- BOD1L1 | c.5075G>A p.S1692N | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CADPS2 | c.2855G>C p.R952T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- CAPRIN1 | c.356T>C p.L119P | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHRNA4 | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- CLEC17A | c.646+4_646+7del p.X216_splice | Splice Site (DEL) | VAF 8/38 reads (21%) | called by pindel, varscan2
- CPAMD8 | c.1120G>T p.G374W (on ENST00000651564; = p.G327W on NM_015692.5) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP2C9 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH11 | c.3918del p.F1306Lfs*11 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- DNAJC17 | c.724C>G p.L242V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DNAJC6 | c.2152_2153dup p.M718Ifs*38 | Frame Shift Ins (INS) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- EXD2 | c.1090G>A p.D364N (on ENST00000312994 / NM_001193362.1; = p.D239N on NM_018199.3) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- FANK1 | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXR1 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GOLGB1 | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GRB7 | c.1405dup p.L469Pfs*29 | Frame Shift Ins (INS) | VAF 8/73 reads (11%) | called by mutect2, pindel, varscan2
- IRS4 | c.3457G>T p.A1153S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); called by mutect2, varscan2
- JUN | c.226_227dup p.E77Wfs*4 | Frame Shift Ins (INS) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- KCNIP1 | c.156G>T p.Q52H (on ENST00000411494 / NM_001034837.3; = p.Q41H on NM_014592.4) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.065); called by muse, mutect2
- KIAA0895 | c.224T>C p.L75P (on ENST00000297063 / NM_001100425.2; = p.L24P on NM_015314.3) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRIF1 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- MAGI2 | c.2579G>C p.R860T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- MATR3 | c.930C>G p.I310M | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MINDY2 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | called by muse, varscan2
- ODAPH | c.176C>A p.T59K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4A5 | c.775G>T p.V259F | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PCDHGA6 | c.1535G>A p.G512E | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCED1B | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- PRG2 | c.17T>G p.L6R | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- PWWP2A | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- QRICH2 | c.3235G>A p.E1079K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- RECQL5 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RERE | c.4372C>A p.P1458T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAXO1 | c.843G>T p.W281C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMC3 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- STARD13 | c.2627C>G p.A876G (on ENST00000336934 / NM_001243476.3; = p.A758G on NM_052851.3) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STT3B | c.2040G>T p.R680S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYT4 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TAF3 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TENM4 | c.5446C>T p.R1816C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- THSD7B | c.4048_4078del p.L1350Sfs*2 (on ENST00000272643; = p.L1348Sfs*2 on NM_001316349.2) | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- TRIM15 | c.243_244del p.Y82Lfs*61 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- TRPM4 | c.2714G>T p.R905L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP9Y | c.16C>G p.H6D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- VXN | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC141 | c.2406C>G p.L802= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV99837621; called by muse, mutect2
- CD1B | c.363G>A p.E121= | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- CLEC14A | c.447C>T p.T149= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs757600652, COSV60561945; called by muse, mutect2, varscan2
- GPR12 | c.363C>T p.V121= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs757364916; called by muse, mutect2
- IGLV1-40 | c.204C>T p.L68= | Silent (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- KCNA5 | c.621C>T p.D207= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as rs779034667; called by muse, mutect2
- KRTAP3-2 | c.90C>G p.V30= | Silent (SNP) | VAF 40/385 reads (10%) | called by muse, mutect2, varscan2
- MAP1B | c.462C>A p.S154= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV57102376; called by muse, mutect2, varscan2
- MGAT3 | c.1176C>T p.F392= | Silent (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- MRGPRF | c.822C>T p.Y274= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs144312357; called by muse, mutect2, varscan2
- MYCT1 | c.426C>T p.L142= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1024080028, COSV65891551; called by muse, mutect2, varscan2
- NWD1 | c.4326C>G p.S1442= | Silent (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- PCDHA2 | c.6G>A p.A2= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs782082810, COSV65369998; called by muse, mutect2, varscan2
- PCDHGB1 | c.1644G>A p.V548= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99528830; called by muse, mutect2, varscan2
- PDZRN4 | c.2049C>A p.I683= (on ENST00000402685 / NM_001164595.2; = p.I425= on NM_013377.4) | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- POR | c.1563C>T p.F521= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- PPIL4 | c.387G>A p.V129= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs762327700; called by muse, mutect2, varscan2
- PTPRT | c.2187C>A p.T729= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100630803; called by muse, mutect2, varscan2
- SCARF2 | c.1662G>A p.S554= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs542257135, COSV56731478; called by muse, mutect2, varscan2
- SCN7A | c.681A>C p.V227= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- SEMA6A | c.2103C>T p.S701= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99145659; called by muse, mutect2, varscan2
- TBX19 | c.1290G>A p.A430= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs1379645001, COSV63197707; called by muse, mutect2, varscan2
- TFAP2A | c.666C>G p.L222= (on ENST00000482890; = p.L214= on NM_001032280.3) | Silent (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- TNFRSF1A | c.456G>A p.G152= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- TRDV3 | c.21T>C p.F7= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- AP000769.5 | chr11:65499529 G>C | 5'Flank (SNP) | VAF 11/82 reads (13%) | catalogued as rs1326515184; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65501051 G>C | 5'Flank (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
